Somatic mutation profile of tumor specimen C3L-06374-54 (aliquot CPT0410490002) from CPTAC case C3L-06374, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 70.6 years (25,791 days).
Specimen C3L-06374-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 277e2174-53c8-4aab-97e9-604967084506.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06374-50 (Buccal Cell Normal), aliquot CPT0410460001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a61bf3ba-3e4d-4227-856b-1f74f5d3d84c

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1205666735, COSV99390791; called by muse, mutect2
- DNMT3A | c.2150A>G p.N717S | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV53041684; called by muse, mutect2, varscan2
- ADGRA2 | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IBA57 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMX | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SCCPDH | c.698G>C p.W233S | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- U2SURP | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CNTNAP1 | c.2598C>T p.D866= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs1442972572; called by muse, mutect2, varscan2
- TTLL8 | c.1881G>A p.A627= | Silent (SNP) | VAF 63/177 reads (36%) | catalogued as rs1267279971; called by muse, mutect2, varscan2
- CCNA1 | c.*6del | 3'UTR (DEL) | VAF 56/190 reads (29%) | called by mutect2, varscan2
